Surgical pathology report (de-identified scan), TCGA case TCGA-58-8391, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8391-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

lung, right: 18.0 x 9.0 x 9.0 cm

tumor central: 10.0 x 6.0 x 6.0 cm

Diagnosis:

Squamous Cell Carcinoma subtype (NOS)

Infiltration into bronchus

pT2, pN2 (3/31), pMx, G2

Pathologist: [REDACTED]

[REDACTED]

Date:

Source: NCI Genomic Data Commons file 0bf0d52b-e59f-4c2b-94db-40c3861cd716 (TCGA-58-8391.ACA4CC6C-A56B-4936-B459-B4C48892924A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).